Somatic mutation profile of tumor specimen TCGA-BR-8371-01A (aliquot TCGA-BR-8371-01A-11D-2340-08) from TCGA case TCGA-BR-8371, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 62.7 years (22,883 days).
Specimen TCGA-BR-8371-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45fafb0d-2d23-4a33-acba-a0452de6fdb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8371-10A (Blood Derived Normal), aliquot TCGA-BR-8371-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b78ee05-dce8-4a9a-b8d0-d50d45ace5d7

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 14, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB3 | c.3934C>G p.P1312A | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99482987, COSV99483918; called by muse, mutect2
- BAP1 | c.734T>C p.L245P | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56237987; called by muse, mutect2, varscan2
- BEST3 | c.1388A>C p.H463P | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV58303467; called by muse, mutect2
- C20orf194 | c.2908C>T p.P970S | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99330372; called by muse, mutect2
- CAP2 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as rs367682004; called by muse, mutect2, varscan2
- CDH3 | c.1191T>A p.D397E | Missense Mutation (SNP) | VAF 21/359 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50563508; called by muse, mutect2
- CDK4 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99225895; called by muse, mutect2
- CNTN6 | c.2545G>A p.E849K | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV63167984, COSV63170441; called by muse, mutect2
- CRX | c.434C>A p.P145H | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as COSV55757103; called by muse, mutect2
- KHDRBS2 | c.911A>G p.D304G | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV55474260; called by muse, mutect2
- MAGEB3 | c.104A>G p.K35R | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.234); catalogued as COSV100854749, COSV64397424, COSV64397481; called by muse, mutect2
- NECAP1 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.051); catalogued as COSV60250061; called by muse, mutect2
- SCAF4 | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1170250276, COSV99741041; called by muse, mutect2
- TNC | c.2524G>A p.V842M | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.631); catalogued as rs1264066759, COSV100406229, COSV60787818; called by muse, mutect2, varscan2
- ADCY8 | c.1752T>G p.T584= | Silent (SNP) | VAF 8/138 reads (6%) | catalogued as COSV53899574, COSV53915819; called by muse, mutect2
- ATP8A2 | c.2463C>T p.D821= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as rs759374071, COSV54947644; called by muse, mutect2
- MMGT1 | c.177T>C p.G59= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV60003306; called by muse, mutect2, varscan2
- PTPN14 | c.1854T>C p.H618= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV65286088; called by muse, mutect2
- SNX18 | c.1551C>T p.P517= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as COSV57990934; called by muse, mutect2
